Somatic mutation profile of tumor specimen TCGA-D8-A141-01A (aliquot TCGA-D8-A141-01A-11D-A10Y-09) from TCGA case TCGA-D8-A141, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 40.0 years (14,626 days).
Specimen TCGA-D8-A141-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c923789c-1a9e-48e9-b436-7c71fac98a77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A141-10A (Blood Derived Normal), aliquot TCGA-D8-A141-10A-01D-A110-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1892f2ed-5345-42ef-ba5a-b3ab352cf020

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 71/193 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATL3 | c.935A>G p.N312S | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.255); catalogued as rs765720770, COSV100219653; called by muse, mutect2, varscan2
- CAMSAP3 | c.3617C>T p.S1206L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs1335705394, COSV50336734; called by muse, mutect2
- DACH1 | c.1460G>A p.R487H (on ENST00000619232 / NM_001366712.1; = p.R435H on NM_080759.6) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1192436758, COSV57496625; called by muse, mutect2
- GP1BA | c.1802C>G p.S601W | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); catalogued as rs374187529, COSV56699688, COSV56699724; called by muse, mutect2, varscan2
- GPKOW | c.431C>A p.A144E | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.96); PolyPhen benign (0.138); catalogued as COSV50242954; called by muse, mutect2, varscan2
- KCNK2 | c.1162C>T p.H388Y (on ENST00000444842 / NM_001017425.3; = p.H373Y on NM_014217.4) | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.015); catalogued as COSV67206623; called by muse, mutect2, varscan2
- NEK3 | c.374del p.H125Pfs*17 | Frame Shift Del (DEL) | VAF 72/294 reads (24%) | catalogued as COSV51617369; called by mutect2, pindel, varscan2
- RUNX1 | c.427+1G>C p.X143_splice (on ENST00000344691 / NM_001001890.3; = p.X170_splice on NM_001754.5) | Splice Site (SNP) | VAF 25/194 reads (13%) | catalogued as CS1312704, COSV55869348, COSV55878661; called by muse, mutect2, varscan2
- SLC46A1 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1422953742, COSV58708316; called by muse, mutect2, varscan2
- THNSL1 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.197); catalogued as COSV64479416; called by muse, mutect2, varscan2
- TLR8 | c.113A>G p.E38G (on ENST00000218032 / NM_138636.5; = p.E56G on NM_016610.4) | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV54318448; called by muse, mutect2, varscan2
- TRHDE | c.1849C>G p.Q617E | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1211108472, COSV53847133; called by muse, mutect2, varscan2
- TRIM11 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs759457960, COSV52858140, COSV99488935; called by muse, mutect2, varscan2
- ZMYM3 | c.3908A>G p.Y1303C | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58736712; called by muse, mutect2, varscan2
- EIF2AK3 | c.1611G>T p.T537= | Silent (SNP) | VAF 28/201 reads (14%) | catalogued as COSV57548389; called by muse, mutect2, varscan2
- H2AC8 | c.165G>A p.V55= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV55127006; called by muse, mutect2, varscan2
- RECQL4 | c.1887G>A p.R629= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV52879944; called by muse, mutect2, varscan2
- TRERF1 | c.2070G>A p.P690= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs780688413, COSV61669652; called by muse, varscan2
